Somatic mutation profile of tumor specimen TCGA-56-5897-01A (aliquot TCGA-56-5897-01A-11D-1632-08) from TCGA case TCGA-56-5897, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.2 years (27,118 days).
Specimen TCGA-56-5897-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ca99426-bfd7-4450-9a8c-cbb5d56b2305.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-5897-10A (Blood Derived Normal), aliquot TCGA-56-5897-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10a4864e-6e77-4b7f-ae1f-afb8bf361c94

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 21 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 21, Nonsense Mutation 7, Frame Shift Del 4, Intron 3, 3'Flank 2, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTEN | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as rs1060500116, CM043772, CM110148, COSV64294267, COSV64296058, COSV64298758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV58052416; called by muse, mutect2, varscan2
- ACACB | c.3493T>A p.S1165T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV58136948; called by muse, mutect2
- ACP3 | c.457T>C p.L153= | Splice Region (SNP) | VAF 30/101 reads (30%) | catalogued as rs1327797451, COSV60486904; called by muse, mutect2, varscan2
- AKAP13 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV63461212; called by muse, mutect2, varscan2
- ANK2 | c.2273C>A p.T758N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100005128, COSV52151735; called by muse, mutect2
- ARHGAP11A | c.2062A>G p.I688V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV55706899; called by muse, mutect2, varscan2
- ASTN2 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV57787272; called by muse, mutect2, varscan2
- ATF7IP | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.072); catalogued as COSV53772433; called by muse, mutect2, varscan2
- BSN | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV56520529; called by muse, mutect2
- BSN | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs977844076, COSV56513022; called by muse, mutect2, varscan2
- C1S | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61071179; called by muse, mutect2, varscan2
- C3 | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV55574757; called by muse, mutect2, varscan2
- CALCOCO1 | c.1299A>G p.I433M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.305); catalogued as COSV50415202; called by muse, mutect2, varscan2
- CLPTM1 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV61612201; called by muse, mutect2, varscan2
- COG5 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.123); catalogued as COSV51754082; called by muse, mutect2, varscan2
- COQ8A | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.058); catalogued as rs1426946846, COSV64658102; called by muse, mutect2, varscan2
- DDI2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV60780036; called by muse, mutect2, varscan2
- DOCK11 | c.4846G>C p.E1616Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52240984; called by muse, mutect2, varscan2
- DPH1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs746459215, COSV53985076; called by muse, mutect2, varscan2
- F5 | c.3096G>C p.K1032N | Missense Mutation (SNP) | VAF 9/257 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV63125076; called by muse, mutect2
- FCAMR | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs551593682, COSV61368101; called by muse, mutect2, varscan2
- GABRB3 | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV54669135, COSV54681518; called by muse, mutect2, varscan2
- GABRG1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs764481527, COSV54956012; called by muse, mutect2, varscan2
- HRH4 | c.1035G>T p.W345C | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56928407; called by muse, mutect2, varscan2
- HSPA4 | c.1487C>G p.S496C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV59182662; called by muse, mutect2
- IQSEC3 | c.2739C>G p.S913R (on ENST00000538872 / NM_001170738.2; = p.S610R on NM_015232.1) | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV58286080; called by muse, mutect2
- KMT2D | c.5435C>G p.S1812* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV56451598; called by muse, mutect2, varscan2
- LRP6 | c.2780G>T p.R927M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV53788991; called by muse, mutect2, varscan2
- MAGEE1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV63910618; called by muse, mutect2, varscan2
- MAST4 | c.848G>A p.R283H (on ENST00000403625 / NM_001164664.2; = p.R94H on NM_015183.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55129255; called by muse, mutect2
- MTA3 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.272); catalogued as COSV63196917; called by muse, mutect2
- MYH8 | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV67966868; called by muse, mutect2, varscan2
- NAV3 | c.3137G>A p.G1046E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99888632; called by muse, mutect2, varscan2
- NKAIN2 | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV63663606, COSV63668176; called by muse, mutect2, varscan2
- NOM1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV51980558; called by muse, mutect2, varscan2
- NOP2 | c.1781C>G p.S594C (on ENST00000322166 / NM_001258308.2; = p.S590C on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100351390, COSV59111473; called by muse, mutect2
- OPRK1 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55571282; called by muse, mutect2, varscan2
- OR5D18 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs377604728; called by muse, mutect2, varscan2
- P2RY10 | c.436C>G p.R146G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV50680349, COSV50682090; called by muse, mutect2, varscan2
- PLA2G15 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); catalogued as rs964424806, COSV54723479; called by muse, mutect2, varscan2
- PLXNB2 | c.4448A>T p.N1483I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63782404; called by muse, varscan2
- PMFBP1 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV52822181, COSV52825957; called by muse, mutect2, varscan2
- PMS1 | c.2293C>T p.H765Y | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV59717096; called by muse, mutect2
- PRDM2 | c.4983G>C p.L1661F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.063); catalogued as COSV52448894; called by muse, mutect2
- PTPRD | c.1763G>T p.R588L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.22); catalogued as COSV61956062; called by muse, mutect2, varscan2
- PTPRH | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54746480; called by muse, mutect2, varscan2
- RASAL2 | c.2044C>G p.Q682E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs1372291219, COSV62715861; called by muse, mutect2, varscan2
- RASGRF2 | c.865G>T p.V289F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54131808; called by muse, mutect2, varscan2
- RHCG | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV51516523; called by muse, mutect2, varscan2
- RIMS1 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53461415; called by muse, mutect2, varscan2
- ROS1 | c.1150A>T p.I384F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV63856528; called by muse, mutect2
- SCN10A | c.5612T>C p.M1871T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV71861797; called by muse, mutect2, varscan2
- SNRPD1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV55932924; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by mutect2, varscan2
- TAAR6 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV51583909, COSV99256527; called by muse, mutect2, varscan2
- TRIML1 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as COSV60194531, COSV60194767; called by muse, mutect2, varscan2
- TTN | c.35108C>A p.P11703Q (on ENST00000591111; = p.P10776Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | PolyPhen benign (0.007); catalogued as COSV60128116; called by muse, mutect2
- UGT3A1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57099103; called by muse, mutect2
- VEPH1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759906036, COSV62878982; called by muse, mutect2
- ZNF3 | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.159); catalogued as COSV52796052; called by muse, mutect2, varscan2
- ZNF398 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV60065603; called by muse, mutect2, varscan2
- ZNF780B | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as COSV55465187; called by muse, mutect2, varscan2
- ZNF804B | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV60831186, COSV60832295; called by mutect2, varscan2
- ACHE | c.582del p.S195Afs*34 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- GPLD1 | c.659del p.G220Vfs*4 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- LENG8 | c.490del p.A164Lfs*16 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- SPATA2L | c.1041del p.R347Sfs*250 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel, varscan2
- ACIN1 | c.937A>C p.R313= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV52977556; called by muse, mutect2
- AGPAT1 | c.717G>T p.T239= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV61247738, COSV61247900; called by muse, mutect2, varscan2
- C19orf47 | c.1083T>G p.L361= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV63509503; called by muse, mutect2, varscan2
- CHKB | c.594G>A p.Q198= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs1555894626, COSV56417232; ClinVar: likely benign; called by muse, mutect2
- DST | c.3834T>A p.I1278= (on ENST00000361203 / NM_001374722.1; = p.I952= on NM_001723.6) | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV55020867; called by muse, mutect2
- ENPEP | c.228C>T p.D76= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs750134233, COSV54452501; called by muse, mutect2, varscan2
- FAM47C | c.2301T>A p.P767= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV63727385; called by muse, mutect2, varscan2
- GRIA3 | c.780C>A p.V260= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV52066191; called by muse, varscan2
- HSPB8 | c.324G>A p.E108= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV56138354; called by muse, mutect2, varscan2
- NABP1 | c.537A>G p.L179= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs771863144, COSV57138944; called by muse, mutect2, varscan2
- NOL4 | c.1641C>A p.I547= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV52350218, COSV52359235; called by muse, mutect2
- OR10X1 | c.336T>A p.G112= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV63767494; called by muse, mutect2, varscan2
- PEX5L | c.558A>G p.R186= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV55848074; called by muse, mutect2, varscan2
- RSPH10B | c.2260C>A p.R754= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as COSV58073304, COSV58074236; called by muse, mutect2, varscan2
- SLC17A5 | c.1446A>G p.V482= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV63287642, COSV63289042; called by muse, mutect2, varscan2
- SNX29 | c.282C>G p.L94= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV73754462; called by muse, mutect2, varscan2
- TAF1L | c.27G>A p.L9= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs756789042, COSV54263409; called by mutect2, varscan2
- TMPRSS15 | c.1374T>C p.Y458= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53041639; called by muse, mutect2
- UNC5D | c.1065A>G p.T355= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs1241893912, COSV54802632; called by muse, mutect2
- ZFHX4 | c.8068T>C p.L2690= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV51438359; called by muse, mutect2
- ZNF20 | c.672G>A p.V224= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV61999654; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83748A>G | Intron (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- AL590867.2 | n.446G>A | RNA (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- AP3S1 | chr5:115841659 T>C | 5'Flank (SNP) | VAF 7/105 reads (7%) | catalogued as COSV57243278; called by muse, mutect2
- FAM160A2 | c.1435+41G>C | Intron (SNP) | VAF 13/95 reads (14%) | catalogued as COSV56410535, COSV99791881; called by muse, mutect2, varscan2
- HBD | chr11:5232780 C>T | 3'Flank (SNP) | VAF 4/19 reads (21%) | catalogued as rs952770382, COSV99496627; called by muse, mutect2
- NRP1 | c.981+4593A>T | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- VPS26C | chr21:37221514 T>C | 3'Flank (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
